Somatic mutation profile of tumor specimen C3N-03877-01 (aliquot CPT0237550010) from CPTAC case C3N-03877, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.9 years (19,674 days).
Specimen C3N-03877-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ed841f-416e-40fd-b194-c299c3e9743c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03877-31 (Blood Derived Normal), aliquot CPT0237610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0bdc2aa-a4da-430d-98a5-b5e25a3178ab

The open-access MAF lists 155 somatic variants for this specimen: 111 protein-altering or splice-affecting, 28 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 28, Nonsense Mutation 10, Intron 6, RNA 5, Frame Shift Del 4, Splice Site 3, 3'UTR 3, Splice Region 2, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 206/349 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.3040G>T p.D1014Y | Missense Mutation (SNP) | VAF 133/386 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV64984576; called by muse, mutect2
- ADH7 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 124/204 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs753958832; called by muse, mutect2, varscan2
- AGBL1 | c.3199G>T p.A1067S | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs369790993; called by muse, mutect2
- ANKFN1 | c.1918G>T p.V640L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs763328804, COSV100593921, COSV59453373, COSV59462313; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1183588455; called by muse, mutect2, varscan2
- CCDC125 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as rs1468295387, COSV67288568; called by muse, varscan2
- CFAP54 | c.7030G>T p.V2344L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.043); catalogued as COSV61570710; called by muse, mutect2, varscan2
- CNTNAP2 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 94/244 reads (39%) | catalogued as COSV62197909, COSV62201663; called by mutect2, varscan2
- COL11A1 | c.1971G>T p.R657S | Missense Mutation (SNP) | VAF 194/432 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100615411, COSV100616568; called by muse, mutect2, varscan2
- CP | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 226/475 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52831060; called by muse, mutect2, varscan2
- CSF1R | c.2442T>C p.N814= | Splice Region (SNP) | VAF 65/189 reads (34%) | catalogued as COSV53834411; called by muse, mutect2, varscan2
- CTNND2 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100476970, COSV58909274; called by muse, mutect2, varscan2
- FAM135B | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52705338; called by muse, mutect2, varscan2
- FAM71F2 | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101100649; called by muse, mutect2, varscan2
- GATAD2B | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748051214, COSV100897730; called by muse, mutect2
- HDDC3 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV57746055, COSV57746771; called by muse, mutect2, varscan2
- HECW2 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV53664367; called by muse, mutect2, varscan2
- IFI27L2 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 17/381 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs953075900; called by muse, mutect2
- IRX2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 142/357 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as COSV57413454; called by muse, mutect2, varscan2
- LRP1B | c.5255C>A p.S1752* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV67215776; called by muse, mutect2, varscan2
- MAP3K19 | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs1472049278, COSV59640743; called by muse, mutect2, varscan2
- MSC | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100335622; called by muse, mutect2, varscan2
- MTERF3 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs761594515; called by muse, varscan2
- NCR1 | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 131/501 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV52555308; called by muse, mutect2, varscan2
- NLRP7 | c.277+2T>A p.X93_splice | Splice Site (SNP) | VAF 263/532 reads (49%) | catalogued as COSV60179401; called by muse, mutect2, varscan2
- PAK3 | c.384G>T p.K128N (on ENST00000262836 / NM_001324328.2; = p.K113N on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/88 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53276429; called by muse, mutect2, varscan2
- PCDHGA10 | c.1507del p.V503Yfs*34 | Frame Shift Del (DEL) | VAF 88/266 reads (33%) | catalogued as COSV99545309; called by mutect2, varscan2
- RNF103 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52897426; called by muse, mutect2, varscan2
- RTTN | c.3394G>A p.V1132M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379376898; called by muse, mutect2, varscan2
- SEC24A | c.1818T>A p.F606L | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100524568; called by muse, mutect2, varscan2
- SERPINA11 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 201/324 reads (62%) | catalogued as rs1360643413; called by muse, mutect2, varscan2
- SIGLEC8 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs774807466; called by muse, mutect2, varscan2
- SORCS1 | c.2782G>T p.G928* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV53853995; called by muse, mutect2, varscan2
- SORCS3 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.339); catalogued as COSV63822218; called by muse, mutect2, varscan2
- SYNDIG1 | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs1262202628, COSV65237694; called by muse, mutect2
- TOR1AIP2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as rs1164291784; called by muse, mutect2, varscan2
- TTLL7 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1345161586, COSV53083600; called by muse, mutect2
- TUBGCP2 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 111/391 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as rs1479096733; called by muse, mutect2, varscan2
- ZBED1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 132/374 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs767431020; called by muse, mutect2, varscan2
- ZBTB38 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58542379; called by muse, mutect2, varscan2
- ABCA8 | c.4639C>G p.L1547V | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ACACA | c.5196G>T p.E1732D | Missense Mutation (SNP) | VAF 195/474 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTR3C | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ADAM29 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS2 | c.2543T>A p.V848D | Missense Mutation (SNP) | VAF 134/413 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- ADD3 | c.1900G>T p.D634Y (on ENST00000356080 / NM_001320591.2; = p.D602Y on NM_001121.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- AMER3 | c.1661C>A p.A554E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- ANKFN1 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP15 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP13A3 | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- BTN3A2 | c.729G>T p.R243S | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5AR2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 191/512 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CBLL2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CCDC125 | c.1418C>G p.S473* | Nonsense Mutation (SNP) | VAF 62/193 reads (32%) | called by muse, varscan2
- CDH23 | c.9502C>G p.R3168G | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDR2L | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- CKAP2L | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL11A1 | c.1970G>T p.R657M | Missense Mutation (SNP) | VAF 197/432 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL18A1 | c.1259G>A p.W420* | Nonsense Mutation (SNP) | VAF 54/162 reads (33%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.403); called by muse, mutect2
- DENND6B | c.1139-5G>T | Splice Region (SNP) | VAF 48/156 reads (31%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2731A>T p.K911* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2
- EIF2AK4 | c.2905G>T p.G969* | Nonsense Mutation (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- ESRP2 | c.2072T>A p.L691H (on ENST00000565858 / NM_001365264.1; = p.L681H on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- F2 | c.1325C>G p.S442C | Missense Mutation (SNP) | VAF 130/253 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FAM135B | c.3472G>T p.V1158L | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLOT1 | c.813del p.I272Sfs*26 | Frame Shift Del (DEL) | VAF 122/329 reads (37%) | called by mutect2, pindel*, varscan2*
- GRID1 | c.1182dup p.E395* | Frame Shift Ins (INS) | VAF 54/194 reads (28%) | called by mutect2, pindel, varscan2
- HOXA2 | c.1075T>A p.L359I | Missense Mutation (SNP) | VAF 16/441 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- IGKV1D-8 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 129/382 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM3A | c.3554T>C p.I1185T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4A | c.2366A>G p.E789G | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- KLHDC4 | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LRRC15 | c.188C>A p.T63K | Missense Mutation (SNP) | VAF 45/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MGA | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- NAGA | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 178/624 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); called by mutect2, varscan2
- NKX2-3 | c.783C>A p.S261R | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PCDHA9 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PDE6C | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 139/416 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PPP1R12C | c.453-2A>G p.X151_splice | Splice Site (SNP) | VAF 170/298 reads (57%) | called by muse, mutect2, varscan2
- PRODH2 | c.953C>A p.T318N (on ENST00000301175; = p.T242N on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/418 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTCHD4 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 126/390 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASGRF1 | c.744G>C p.M248I | Missense Mutation (SNP) | VAF 226/558 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RGS3 | c.1142C>G p.P381R (on ENST00000350696 / NM_001282923.2; = p.P269R on NM_017790.4) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RHAG | c.991C>G p.H331D | Missense Mutation (SNP) | VAF 194/625 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RUFY1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RXFP3 | c.336del p.W112Cfs*15 | Frame Shift Del (DEL) | VAF 37/147 reads (25%) | called by mutect2, pindel, varscan2
- RYR2 | c.7871C>A p.P2624H | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SHCBP1 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SREBF2 | c.3397G>T p.G1133C | Missense Mutation (SNP) | VAF 200/635 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ST6GALNAC1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 83/299 reads (28%) | PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STRA6 | c.1319T>C p.I440T | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAS2R50 | c.510T>A p.N170K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TMEM132C | c.840C>G p.S280R | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAPPC12 | c.1776+1G>A p.X592_splice | Splice Site (SNP) | VAF 105/287 reads (37%) | called by muse, mutect2, varscan2
- TRIM58 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TSGA13 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- TTC30B | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- TUBA1B | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 115/355 reads (32%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- UCKL1 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by mutect2, varscan2
- USH2A | c.13835G>T p.C4612F | Missense Mutation (SNP) | VAF 96/155 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTRN | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS41 | c.2444G>T p.R815L | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- WDR13 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 83/110 reads (75%) | SIFT tolerated (0.78); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- WDR7 | c.2310G>C p.R770S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR97 | c.3924del p.K1309Rfs*20 | Frame Shift Del (DEL) | VAF 86/214 reads (40%) | called by mutect2, pindel, varscan2
- ZBTB37 | c.1245G>T p.Q415H | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF491 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 59/100 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF75D | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | called by muse, mutect2, varscan2
- ZSCAN5A | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 125/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC099489.1 | c.4776C>T p.Y1592= | Silent (SNP) | VAF 67/153 reads (44%) | catalogued as rs775054716; called by muse, mutect2, varscan2
- ARID4B | c.2367A>G p.L789= | Silent (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- COL22A1 | c.3852T>A p.S1284= | Silent (SNP) | VAF 132/636 reads (21%) | called by muse, mutect2, varscan2
- CPSF1 | c.336C>T p.T112= | Silent (SNP) | VAF 231/463 reads (50%) | called by muse, mutect2, varscan2
- DNAH5 | c.4041G>T p.L1347= | Silent (SNP) | VAF 111/331 reads (34%) | called by muse, mutect2, varscan2
- DNAH8 | c.8808A>G p.E2936= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs745722973; called by muse, mutect2, varscan2
- EIPR1 | c.228C>T p.D76= | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- FGF23 | c.702G>A p.T234= | Silent (SNP) | VAF 46/548 reads (8%) | catalogued as COSV52975742, COSV52976300; called by muse, mutect2
- KAT2B | c.384A>T p.I128= | Silent (SNP) | VAF 69/151 reads (46%) | called by muse, mutect2, varscan2
- KIF7 | c.3886C>A p.R1296= | Silent (SNP) | VAF 146/325 reads (45%) | catalogued as COSV51541735, COSV99177101; called by muse, mutect2, varscan2
- MMP24 | c.660C>T p.I220= | Silent (SNP) | VAF 187/571 reads (33%) | called by muse, mutect2, varscan2
- MUC22 | c.780C>A p.A260= | Silent (SNP) | VAF 67/170 reads (39%) | called by muse, mutect2, varscan2
- MUC4 | c.4470T>A p.P1490= | Silent (SNP) | VAF 113/650 reads (17%) | called by muse, mutect2
- NASP | c.1950A>G p.R650= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- NCBP3 | c.1161C>T p.S387= | Silent (SNP) | VAF 28/250 reads (11%) | catalogued as rs879066882, COSV50107353; called by muse, mutect2, varscan2
- NDFIP1 | c.219G>A p.L73= | Silent (SNP) | VAF 55/189 reads (29%) | called by muse, mutect2, varscan2
- NFRKB | c.1702C>T p.L568= (on ENST00000446488 / NM_001143835.2; = p.L593= on NM_006165.3) | Silent (SNP) | VAF 123/204 reads (60%) | called by muse, mutect2, varscan2
- PCDHB14 | c.1245C>T p.A415= | Silent (SNP) | VAF 156/447 reads (35%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1821G>T p.L607= | Silent (SNP) | VAF 292/1198 reads (24%) | called by muse, varscan2
- PDZRN3 | c.1374A>C p.A458= | Silent (SNP) | VAF 105/188 reads (56%) | called by muse, mutect2, varscan2
- PGP | c.231C>T p.Y77= | Silent (SNP) | VAF 137/321 reads (43%) | called by muse, mutect2, varscan2
- SALL3 | c.3330C>A p.P1110= | Silent (SNP) | VAF 134/377 reads (36%) | called by muse, mutect2, varscan2
- SERPINB3 | c.741G>A p.L247= | Silent (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- SLC7A13 | c.246T>C p.Y82= | Silent (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- SOAT1 | c.1167C>G p.L389= | Silent (SNP) | VAF 23/227 reads (10%) | catalogued as rs1419093179; called by muse, mutect2
- SPEF2 | c.753C>T p.F251= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs112202508, COSV56798319; called by muse, mutect2, varscan2
- TENT5A | c.795T>C p.Y265= | Silent (SNP) | VAF 29/106 reads (27%) | called by muse, mutect2, varscan2
- TOP3B | c.2415C>T p.P805= | Silent (SNP) | VAF 173/480 reads (36%) | catalogued as rs765129084, COSV54286972; called by muse, mutect2, varscan2
- AC079154.1 | n.1030G>T | RNA (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- AL358333.1 | chr14:51979290 C>T | 3'Flank (SNP) | VAF 44/427 reads (10%) | called by muse, mutect2, varscan2
- ANO4 | c.-53G>T | 5'UTR (SNP) | VAF 93/270 reads (34%) | catalogued as COSV100151614; called by muse, mutect2, varscan2
- FOLH1B | n.1054G>T | RNA (SNP) | VAF 81/159 reads (51%) | called by muse, mutect2, varscan2
- HKDC1 | c.*777dup | 3'UTR (INS) | VAF 23/59 reads (39%) | called by mutect2, varscan2
- HLA-F | c.64+9G>A | Intron (SNP) | VAF 63/180 reads (35%) | called by muse, mutect2, varscan2
- IPO7 | c.84+7395A>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1396254923; called by muse, mutect2, varscan2
- IRX2 | c.*7C>T | 3'UTR (SNP) | VAF 40/167 reads (24%) | catalogued as rs764100488; called by muse, mutect2, varscan2
- KCNH2 | c.1945+37A>T | Intron (SNP) | VAF 117/241 reads (49%) | called by muse, mutect2, varscan2
- MLIP | c.64-9932del | Intron (DEL) | VAF 57/228 reads (25%) | called by mutect2, pindel, varscan2
- NBPF22P | n.370C>A | RNA (SNP) | VAF 200/656 reads (30%) | called by muse, mutect2, varscan2
- OBP2B | c.277+219G>T | Intron (SNP) | VAF 121/213 reads (57%) | catalogued as rs781916196; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3163C>T | RNA (SNP) | VAF 5/15 reads (33%) | catalogued as rs769055735; called by muse, mutect2, varscan2
- SEC31B | c.496-419G>T | Intron (SNP) | VAF 54/162 reads (33%) | called by muse, mutect2, varscan2
- U82695.1 | n.1825C>T | RNA (SNP) | VAF 199/271 reads (73%) | called by muse, mutect2, varscan2
- ZNF99 | c.*1068C>T | 3'UTR (SNP) | VAF 62/87 reads (71%) | catalogued as rs1335964369; called by muse, mutect2, varscan2
